Gene-level copy-number profile of tumor specimen TCGA-CK-6748-01A from TCGA case TCGA-CK-6748, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 45.3 years (16,529 days).
Specimen TCGA-CK-6748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.8760666a-cc08-42db-935a-4b6095d138ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CK-6748-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b20a748-0504-4e14-adb6-a815184c5d8c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 157; copy number 2: 19,455; copy number 3: 35,030; copy number 4: 2,887; copy number 6: 452; copy number 7: 1,838.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CK-6748-01A-11D-1834-01): tumor purity 0.72, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,838 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr20:40,685,848–60,653,784, 447 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
